Gene-level copy-number profile of tumor specimen TCGA-D3-A3CB-06A from TCGA case TCGA-D3-A3CB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 46.9 years (17,125 days).
Specimen TCGA-D3-A3CB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9016164e-e89c-4324-a8eb-64973888c8d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A3CB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69f1f21a-9ced-47e2-81d0-f517784ab882

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 813; copy number 2: 37,896; copy number 3: 12,796; copy number 4: 3,707; copy number 5: 4,607.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A3CB-06A-11D-A194-01): tumor purity 0.27, ploidy 2.42, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,607 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (broad region; genes not listed).
- chr8:46,579,213–145,066,685, 1,532 genes, copy number 5 (broad region; genes not listed).
- chr14:22,007,512–22,495,966, 61 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
